FM case AD8397 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts.
https://portal.gdc.cancer.gov/cases/6d44b6ab-8836-472e-b00d-6dc41e225d92

Female, 22.0 years: Hepatocellular carcinoma, NOS (ICD-O-3 8170/3) of the liver; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
